Somatic mutation profile of tumor specimen 0E1HF1 from CCDI case PBCVTZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E1HF1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bdf20545-e07e-4f2e-b43d-24ff707726b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1HFX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76e1e061-7f59-488b-86db-ba8c8097f798

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, 3'UTR 2, Frame Shift Ins 1, Frame Shift Del 1, 5'Flank 1, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SETD2 | c.5481G>T p.W1827C | Missense Mutation (SNP) | VAF 69/249 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57429720; called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- GADD45A | c.339dup p.E114Rfs*48 | Frame Shift Ins (INS) | VAF 29/199 reads (15%) | called by mutect2, pindel, varscan2
- LPIN3 | c.796C>A p.L266I | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- RAD51B | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 14/342 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC4A3 | c.1245del p.S416Afs*8 | Frame Shift Del (DEL) | VAF 16/116 reads (14%) | called by mutect2, pindel
- SPEG | c.3853C>A p.P1285T | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- BTBD11 | c.3180C>T p.N1060= (on ENST00000280758 / NM_001018072.2; = p.N597= on NM_001017523.2) | Silent (SNP) | VAF 61/214 reads (29%) | catalogued as rs138617821, COSV55025421; called by muse, mutect2, varscan2
- ACOT13 | c.82-10204G>A | Intron (SNP) | VAF 18/222 reads (8%) | catalogued as rs1267872617, COSV100015853; called by muse, mutect2
- ARIH2 | chr3:48918806 C>A | 5'Flank (SNP) | VAF 4/38 reads (11%) | catalogued as rs779523412; called by mutect2, varscan2
- EMC6 | c.*30A>C | 3'UTR (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- TRIM46 | c.*51del | 3'UTR (DEL) | VAF 3/24 reads (13%) | catalogued as COSV100104987; called by pindel, varscan2
